Somatic mutation profile of tumor specimen BA2606D (aliquot aq-BA2606D) from BEATAML1.0 case 2024, project BEATAML1.0-COHORT (Functional Genomic Landscape of Acute Myeloid Leukemia). Sex at birth: male; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 60.7 years (22,155 days).
Specimen BA2606D: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7a3d8faf-e222-4582-ba5f-8b52c8de1f68.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BA2331D (Solid Tissue Normal), aliquot aq-BA2331D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4c48fad9-edcb-406e-b748-4fc95211d610

The open-access MAF lists 20 somatic variants for this specimen: 15 protein-altering or splice-affecting, 3 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 11, Silent 3, Frame Shift Del 3, Intron 1, 3'UTR 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH1 | c.394C>T p.R132C | Missense Mutation (SNP) | VAF 35/135 reads (26%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.03); PolyPhen benign (0.1); catalogued as rs121913499, CM1111831, COSV61615256, COSV61615456, COSV61615649; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- SOS1 | c.806T>G p.M269R | Missense Mutation (SNP) | VAF 46/309 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.616); catalogued as rs137852813, CM070275, CM074570, COSV67674247, COSV67676625; ClinVar: pathogenic; called by muse, mutect2, varscan2
- SRSF2 | c.284C>G p.P95R | Missense Mutation (SNP) | VAF 32/85 reads (38%) | hotspot (GDC flag); SIFT tolerated (0.12); PolyPhen probably damaging (0.987); catalogued as rs751713049, CM1511359, COSV57969809, COSV57969816, COSV57969830; called by muse, varscan2
- GRIK2 | c.1229del p.G410Afs*2 | Frame Shift Del (DEL) | VAF 35/90 reads (39%) | catalogued as COSV100026414; called by mutect2, pindel, varscan2
- ITGA8 | c.2684G>A p.R895Q | Missense Mutation (SNP) | VAF 22/171 reads (13%) | SIFT tolerated (0.3); PolyPhen benign (0.02); catalogued as rs368464139; called by muse, mutect2, varscan2
- MTUS2 | c.2323A>G p.M775V | Missense Mutation (SNP) | VAF 106/311 reads (34%) | SIFT tolerated (1); PolyPhen benign (0.028); catalogued as rs771889987; called by muse, mutect2, varscan2
- MUC20 | c.1796C>T p.P599L | Missense Mutation (SNP) | VAF 21/99 reads (21%) | SIFT deleterious (0.05); PolyPhen benign (0.042); catalogued as COSV100291328; called by muse, mutect2, varscan2
- OR7G1 | c.806G>A p.R269Q | Missense Mutation (SNP) | VAF 49/165 reads (30%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.794); catalogued as rs769414989, COSV53316818; called by muse, mutect2, varscan2
- ANKS3 | c.19G>T p.E7* | Nonsense Mutation (SNP) | VAF 4/52 reads (8%) | called by muse, mutect2
- ASXL1 | c.2239del p.S747Pfs*25 | Frame Shift Del (DEL) | VAF 34/118 reads (29%) | called by mutect2, pindel, varscan2
- CLDN10 | c.49G>A p.G17R | Missense Mutation (SNP) | VAF 52/171 reads (30%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.752); called by muse, mutect2, varscan2
- DCAF5 | c.2128G>A p.A710T | Missense Mutation (SNP) | VAF 33/106 reads (31%) | SIFT tolerated, low confidence (0.46); PolyPhen benign (0); called by muse, mutect2, varscan2
- SF3A2 | c.615+1del | Frame Shift Del (DEL) | VAF 14/59 reads (24%) | called by mutect2, pindel, varscan2
- ZFYVE27 | c.1021C>A p.R341S | Missense Mutation (SNP) | VAF 6/99 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.84); called by muse, mutect2
- ZNF461 | c.306G>T p.L102F | Missense Mutation (SNP) | VAF 3/41 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.153); called by muse, mutect2
- B3GNT6 | c.508C>A p.R170= | Silent (SNP) | VAF 3/29 reads (10%) | catalogued as rs782196204; called by muse, mutect2
- NBEAL2 | c.1260C>A p.P420= | Silent (SNP) | VAF 39/114 reads (34%) | called by muse, mutect2, varscan2
- PCDHGA5 | c.2131C>T p.L711= | Silent (SNP) | VAF 36/125 reads (29%) | called by muse, mutect2, varscan2
- B4GALNT1 | c.*1326G>A | 3'UTR (SNP) | VAF 27/99 reads (27%) | catalogued as rs368770259, COSV100247147; called by muse, mutect2, varscan2
- PLEKHA5 | c.1846-588T>C | Intron (SNP) | VAF 26/100 reads (26%) | called by muse, mutect2, varscan2
